FM case AD604 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/cd80a1a0-1df8-4a16-9c2f-d47b954d2121

Female, 61.2 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
